Somatic mutation profile of tumor specimen TCGA-TQ-A7RU-01A (aliquot TCGA-TQ-A7RU-01A-21D-A34A-08) from TCGA case TCGA-TQ-A7RU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-TQ-A7RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a691fc-f010-48b8-ae71-c091551c89af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RU-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RU-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5bf9f9-41aa-4e9f-a66a-c370c3d14407

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, varscan2
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 41/68 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/116 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C4BPA | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV65536811; called by muse, mutect2, varscan2
- COLEC10 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV100250663; called by muse, mutect2, varscan2
- EPO | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99402580; called by muse, mutect2, varscan2
- FHL5 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.047); catalogued as COSV100459421; called by muse, mutect2, varscan2
- ITPR3 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs776134726, COSV65408456, COSV65415531; called by muse, mutect2, varscan2
- MAMDC2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs534058708, COSV65858522; called by muse, mutect2, varscan2
- MDGA1 | c.2209A>G p.I737V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs1195590642, COSV99776892; called by muse, mutect2, varscan2
- MRGBP | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100978282; called by muse, mutect2, varscan2
- OCIAD1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99971158; called by muse, mutect2, varscan2
- OLFM4 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV99524334; called by muse, mutect2, varscan2
- PARD6B | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100859936; called by muse, mutect2, varscan2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2, varscan2
- PLS1 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as COSV100538126, COSV100538210; called by muse, mutect2, varscan2
- REV3L | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 85/258 reads (33%) | catalogued as COSV100725200; called by muse, mutect2, varscan2
- SIN3A | c.2258T>C p.I753T | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100845148; called by muse, mutect2, varscan2
- SLC7A1 | c.1625T>C p.V542A | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.044); catalogued as rs1476104496; called by muse, mutect2
- SLC7A13 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1563588424, COSV99878878; called by muse, mutect2
- SLCO1B1 | c.1031T>G p.L344W | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as rs746786269, COSV99918508; called by muse, mutect2, varscan2
- SOS2 | c.1320T>A p.N440K | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99366106; called by muse, mutect2, varscan2
- TDRD6 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100287623; called by muse, mutect2, varscan2
- TMEM70 | c.297T>G p.N99K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100384103; called by muse, mutect2, varscan2
- TRPA1 | c.2933T>C p.M978T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100084174; called by muse, mutect2, varscan2
- BGN | c.195C>T p.F65= | Silent (SNP) | VAF 82/87 reads (94%) | catalogued as rs782354774, COSV59037433; called by muse, mutect2, varscan2
- DNAH7 | c.11676C>T p.Y3892= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs750575502, COSV100415240, COSV56751457; called by muse, mutect2, varscan2
- FZD4 | c.1344A>G p.A448= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as rs1157906125, COSV101536046; called by muse, mutect2, varscan2
- NEK1 | c.1824G>T p.L608= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV101455687; called by muse, mutect2, varscan2
- ST3GAL5 | c.621C>T p.G207= (on ENST00000377332; = p.G247= on NM_003896.4) | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs757539559, COSV60385566; called by muse, mutect2, varscan2
- TPM4 | c.102C>T p.D34= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100783707; called by muse, mutect2
- SKP2 | c.*1892C>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99948078; called by muse, mutect2
